Somatic mutation profile of tumor specimen ALCH-B1KI-TTP1-A (aliquot ALCH-B1KI-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1KI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 66.7 years (24,367 days).
Specimen ALCH-B1KI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b673c202-f095-47e2-82de-4d8519676b36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1KI-NB1-A (Blood Derived Normal), aliquot ALCH-B1KI-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bbf3bb3-a62e-40f5-81b9-99dba0d2f7af

The open-access MAF lists 231 somatic variants for this specimen: 154 protein-altering or splice-affecting, 50 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 50, Intron 14, Nonsense Mutation 13, Splice Site 7, 5'UTR 5, 3'UTR 4, Splice Region 3, RNA 3, Frame Shift Ins 2, Frame Shift Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS2 | c.1515G>A p.A505= | Splice Region (SNP) | VAF 50/237 reads (21%) | catalogued as rs775724420; called by muse, mutect2, varscan2
- ADCYAP1 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1048409261; called by muse, mutect2, varscan2
- ADGRL3 | c.125G>C p.G42A | Missense Mutation (SNP) | VAF 83/431 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101547119; called by muse, mutect2, varscan2
- ALKBH8 | c.80A>T p.H27L | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as rs1236846173; called by muse, mutect2, varscan2
- ALX3 | c.334G>C p.G112R | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs550218304; called by muse, mutect2, varscan2
- APOBEC1 | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 139/375 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV57549893; called by muse, mutect2, varscan2
- ATF7IP | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV99661161; called by muse, mutect2, varscan2
- C5orf24 | c.26A>G p.N9S | Missense Mutation (SNP) | VAF 40/316 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.971); catalogued as COSV100574432; called by muse, mutect2, varscan2
- CALHM3 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1188171454, COSV63921860; called by muse, mutect2
- CAPN8 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs554837985, COSV100838618; called by muse, mutect2, varscan2
- CDH7 | c.1959C>A p.Y653* | Nonsense Mutation (SNP) | VAF 13/72 reads (18%) | catalogued as COSV59886834, COSV59889626; called by muse, mutect2, varscan2
- CHM | c.160G>T p.G54* | Nonsense Mutation (SNP) | VAF 19/263 reads (7%) | catalogued as COSV100718190; called by muse, mutect2
- CNTNAP5 | c.657C>G p.F219L | Missense Mutation (SNP) | VAF 19/391 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV101443772, COSV70502003; called by muse, mutect2
- COL14A1 | c.2518G>T p.E840* | Nonsense Mutation (SNP) | VAF 72/239 reads (30%) | catalogued as COSV52863302; called by muse, mutect2, varscan2
- CR1 | c.5311C>T p.Q1771* | Nonsense Mutation (SNP) | VAF 32/262 reads (12%) | catalogued as rs1375478918, COSV65460323; called by muse, mutect2, varscan2
- CRB2 | c.3751C>T p.R1251C | Missense Mutation (SNP) | VAF 58/290 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs767416221; called by muse, varscan2
- CRISPLD2 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs753278157; called by muse, mutect2, varscan2
- ELAVL4 | c.531C>A p.F177L | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as COSV63915517; called by muse, mutect2
- FLG | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 38/580 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.334); catalogued as rs779690124, COSV64239340; called by muse, mutect2
- FRMPD4 | c.1827G>T p.Q609H | Missense Mutation (SNP) | VAF 83/212 reads (39%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV66213335; called by muse, mutect2, varscan2
- H2AC4 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 56/462 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.956); catalogued as rs138437314; called by muse, mutect2, varscan2
- HGSNAT | c.1750G>A p.V584I | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.443); catalogued as rs550696803, CD065734, COSV99925422; called by muse, mutect2
- HNF1A | c.788G>T p.R263L | Missense Mutation (SNP) | VAF 152/709 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as CM031753, CM064307, COSV57459250, COSV57466458; called by muse, mutect2, varscan2
- HRNR | c.6416G>C p.R2139T | Missense Mutation (SNP) | VAF 81/2134 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs753240264, COSV100913981, COSV64259092; called by muse, mutect2
- IGHV1OR15-9 | c.4G>T p.G2C | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs1223249159; called by muse, mutect2, varscan2
- ITPA | c.11C>G p.S4* | Nonsense Mutation (SNP) | VAF 93/389 reads (24%) | catalogued as COSV100621526; called by muse, mutect2, varscan2
- KDM6A | c.3769G>A p.E1257K | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65039620, COSV65045309; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2588C>T p.S863F | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745353017; called by muse, mutect2, varscan2
- MTRR | c.1961A>T p.D654V (on ENST00000264668; = p.D627V on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 110/270 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs779754195; called by muse, mutect2, varscan2
- NDUFC1 | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as rs1463363007; called by muse, mutect2, varscan2
- OR2G6 | c.642C>G p.I214M | Missense Mutation (SNP) | VAF 87/382 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58575869; called by muse, mutect2, varscan2
- OR4B1 | c.587T>C p.I196T | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs202065024; called by muse, mutect2, varscan2
- PCDH15 | c.4659G>A p.M1553I | Missense Mutation (SNP) | VAF 40/576 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV64684045, COSV64720307; called by muse, mutect2
- PHC3 | c.2507A>C p.H836P (on ENST00000494943 / NM_001308116.2; = p.H848P on NM_024947.4) | Missense Mutation (SNP) | VAF 246/456 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as rs371746840; called by muse, mutect2, varscan2
- PIK3R2 | c.2018C>T p.T673M | Missense Mutation (SNP) | VAF 17/290 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55850965; called by muse, mutect2
- RASA3 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1452773154; called by muse, mutect2
- RET | c.2092G>T p.D698Y | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV60689044; called by muse, mutect2, varscan2
- SEZ6L2 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as rs375170414; called by muse, mutect2, varscan2
- SHISAL2A | c.190G>C p.A64P | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV68979687; called by muse, mutect2, varscan2
- SLC16A12 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs764580534; called by muse, mutect2
- SLC22A6 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs11568634, CM057842; called by muse, mutect2, varscan2
- SLC9A3 | c.2362C>A p.R788S | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV53803808; called by muse, varscan2
- SLITRK3 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 25/391 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as rs757484416, COSV53853902, COSV99579916; called by muse, mutect2
- TERB1 | c.1960C>T p.R654* | Nonsense Mutation (SNP) | VAF 32/176 reads (18%) | catalogued as rs1475837580, COSV57613203; called by muse, mutect2
- THRSP | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 61/389 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV55245975; called by muse, mutect2, varscan2
- UNC5B | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.105); catalogued as rs368026327; called by muse, mutect2
- ZFAT | c.1108A>G p.I370V | Missense Mutation (SNP) | VAF 31/554 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs1233190513; called by muse, mutect2
- ZMYND11 | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1455375173; called by muse, mutect2
- ZNF346 | c.22A>G p.T8A | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1199394746; called by muse, mutect2, varscan2
- ZNF407 | c.3601G>A p.E1201K | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.162); catalogued as COSV55242316; called by muse, mutect2
- ADAM7 | c.1226A>T p.K409M | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.459); called by muse, mutect2
- ADGRA3 | c.2358-1G>C p.X786_splice | Splice Site (SNP) | VAF 14/67 reads (21%) | called by muse, mutect2, varscan2
- AGMO | c.1000C>G p.L334V | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AGO2 | c.2108C>T p.T703I | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AMTN | c.416C>G p.T139S | Missense Mutation (SNP) | VAF 64/292 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ANKRD17 | c.6835A>G p.T2279A | Missense Mutation (SNP) | VAF 134/594 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP2S1 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 27/281 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- ATXN2 | c.2117T>C p.V706A (on ENST00000550104; = p.V546A on NM_002973.4) | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- BMP1 | c.1239G>A p.W413* | Nonsense Mutation (SNP) | VAF 64/338 reads (19%) | called by muse, mutect2, varscan2
- C3 | c.3539A>G p.Y1180C | Missense Mutation (SNP) | VAF 80/413 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1C | c.3274G>A p.E1092K | Missense Mutation (SNP) | VAF 105/279 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CCDC85A | c.605_614del p.P202Rfs*106 | Frame Shift Del (DEL) | VAF 45/108 reads (42%) | called by mutect2, pindel, varscan2
- CDC27 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRD | c.148+2T>C p.X50_splice | Splice Site (SNP) | VAF 23/134 reads (17%) | called by muse, mutect2, varscan2
- CLDN2 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CNTNAP2 | c.733C>A p.L245M | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL14A1 | c.2517G>T p.E839D | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL24A1 | c.2569G>T p.V857F | Missense Mutation (SNP) | VAF 56/332 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- CREB3L3 | c.694A>T p.T232S | Missense Mutation (SNP) | VAF 36/594 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.017); called by muse, mutect2
- CSF2RA | c.1004C>A p.T335N | Missense Mutation (SNP) | VAF 262/746 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CSMD3 | c.10502G>A p.W3501* (on ENST00000297405 / NM_001363185.1; = p.W3332* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 31/198 reads (16%) | called by muse, mutect2, varscan2
- DEPDC1B | c.1004C>G p.A335G | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.03); called by muse, mutect2
- DHX8 | c.3260A>T p.D1087V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- DMD | c.8311G>T p.D2771Y | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, varscan2
- DSCAM | c.3955T>A p.W1319R | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ELMOD1 | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.91); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPX | c.72C>G p.D24E | Missense Mutation (SNP) | VAF 99/478 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ETAA1 | c.2393A>T p.Q798L | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT tolerated (0.24); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ETV5 | c.743C>G p.S248* | Nonsense Mutation (SNP) | VAF 18/184 reads (10%) | called by muse, mutect2
- EVC2 | c.3116A>T p.Q1039L | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- GCC2 | c.2675G>T p.S892I | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDGFL3 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 16/236 reads (7%) | called by muse, mutect2
- HLTF | c.1910T>C p.I637T | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2
- HOXA6 | c.702G>T p.*234Yext*? | Nonstop Mutation (SNP) | VAF 17/80 reads (21%) | called by muse, varscan2
- HOXA9 | c.616A>T p.T206S | Missense Mutation (SNP) | VAF 70/271 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- HSPA4L | c.1181T>C p.I394T | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ITGA5 | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 73/309 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- KALRN | c.8704G>A p.E2902K (on ENST00000360013 / NM_001024660.4; = p.E1205K on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/536 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.287); called by muse, mutect2
- KAT5 | c.13-32_13del p.X5_splice | Splice Site (DEL) | VAF 19/73 reads (26%) | called by mutect2, pindel, varscan2
- KIF6 | c.1772C>A p.A591D | Missense Mutation (SNP) | VAF 17/283 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.169); called by muse, mutect2
- KLHL34 | c.1341C>A p.D447E | Missense Mutation (SNP) | VAF 128/335 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- LIMS2 | c.802+6G>T | Splice Region (SNP) | VAF 123/278 reads (44%) | called by mutect2, varscan2
- LRRC1 | c.83C>G p.P28R | Missense Mutation (SNP) | VAF 23/322 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LSAMP | c.115A>T p.I39F | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MAP7D1 | c.1166G>T p.G389V | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- MBD6 | c.1817C>A p.P606Q | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- MCF2 | c.1658A>T p.Y553F | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MIDN | c.234-5C>G | Splice Region (SNP) | VAF 45/229 reads (20%) | called by muse, mutect2, varscan2
- MORF4L1 | c.52A>G p.N18D | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- MORF4L2 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 9/95 reads (9%) | called by muse, mutect2
- MPP7 | c.793A>T p.M265L | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- MYEF2 | c.921+1G>T p.X307_splice | Splice Site (SNP) | VAF 12/173 reads (7%) | called by muse, mutect2
- NEFM | c.115T>G p.S39A | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); called by muse, mutect2
- NUDT18 | c.146T>A p.V49E | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- OR10V1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2AK2 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR52B2 | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- OR8B8 | c.318C>G p.F106L | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.049); called by muse, mutect2
- OVCH1 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 81/290 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- PAQR9 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 25/527 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.86); called by muse, mutect2
- PCYT1B | c.951G>T p.K317N | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PIGZ | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.028); called by muse, mutect2
- PJA1 | c.377G>T p.S126I | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PLEKHG2 | c.2057C>T p.T686I | Missense Mutation (SNP) | VAF 8/197 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.076); called by muse, mutect2
- POM121 | c.181G>T p.G61W | Missense Mutation (SNP) | VAF 75/238 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POTEH | c.469dup p.W157Lfs*32 | Frame Shift Ins (INS) | VAF 144/1290 reads (11%) | called by pindel, varscan2
- PREX1 | c.4415T>C p.L1472P | Missense Mutation (SNP) | VAF 24/325 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- PTCHD1 | c.205C>A p.L69I | Missense Mutation (SNP) | VAF 46/472 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.127); called by muse, mutect2
- RARG | c.606dup p.S203Lfs*30 | Frame Shift Ins (INS) | VAF 19/101 reads (19%) | called by mutect2, pindel, varscan2
- RBM23 | c.1259C>T p.A420V (on ENST00000359890 / NM_001077351.2; = p.A404V on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- REG1A | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 133/260 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- RGS11 | c.739T>C p.C247R (on ENST00000397770 / NM_183337.3; = p.C226R on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/314 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- RPN1 | c.1666G>C p.A556P | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.127); called by muse, mutect2
- SCN3A | c.1409G>A p.R470K | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.152); called by muse, mutect2
- SIGLEC6 | c.314C>G p.S105C | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SIRPD | c.527C>A p.T176K | Missense Mutation (SNP) | VAF 47/281 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLAIN1 | c.328G>T p.A110S (on ENST00000466548; = p.A132S on NM_001242868.2) | Missense Mutation (SNP) | VAF 105/390 reads (27%) | SIFT tolerated (0.25); called by muse, mutect2, varscan2
- SRCIN1 | c.857G>A p.R286H (on ENST00000621492; = p.R252H on NM_025248.3) | Missense Mutation (SNP) | VAF 29/365 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.993); called by muse, mutect2
- STK31 | c.1911A>C p.K637N | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TAF9B | c.388A>G p.K130E | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, varscan2
- TECTB | c.372C>A p.H124Q | Missense Mutation (SNP) | VAF 11/272 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.009); called by muse, mutect2
- TMEM139 | c.491G>C p.R164P | Missense Mutation (SNP) | VAF 41/274 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- TMEM200A | c.932A>G p.D311G | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNN | c.1855+2T>A p.X619_splice | Splice Site (SNP) | VAF 33/159 reads (21%) | called by muse, mutect2, varscan2
- TNR | c.3183G>T p.W1061C | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNR | c.3182G>T p.W1061L | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRBV5-1 | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TRDN | c.484+1del p.X162_splice | Splice Site (DEL) | VAF 8/20 reads (40%) | called by mutect2, pindel, varscan2
- TRGJP2 | c.14G>A p.W5* | Nonsense Mutation (SNP) | VAF 31/149 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.97288C>G p.P32430A (on ENST00000591111; = p.P25006A on NM_003319.4) | Missense Mutation (SNP) | VAF 16/304 reads (5%) | PolyPhen benign (0.019); called by muse, mutect2
- UGT2B10 | c.1299T>A p.N433K | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- UGT3A2 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 50/343 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- UTP6 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- VAT1L | c.823T>C p.Y275H | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- VEPH1 | c.1729A>G p.I577V | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- VIRMA | c.3304A>G p.I1102V | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR19 | c.2817A>C p.E939D | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- WDR48 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 9/126 reads (7%) | called by muse, mutect2
- ZC2HC1A | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFHX4 | c.10250C>A p.A3417D | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ZNF821 | c.234T>A p.D78E (on ENST00000425432 / NM_001376297.1; = p.D36E on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/492 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.935); called by muse, mutect2
- ZNF821 | c.232G>A p.D78N (on ENST00000425432 / NM_001376297.1; = p.D36N on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/486 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.956); called by muse, mutect2
- ZP1 | c.1014+1G>T p.X338_splice | Splice Site (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2, varscan2
- ZSWIM9 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ACTN3 | c.1077G>A p.L359= | Silent (SNP) | VAF 26/613 reads (4%) | called by muse, mutect2
- AVPR2 | c.198C>G p.G66= | Silent (SNP) | VAF 16/188 reads (9%) | called by muse, mutect2
- BMP15 | c.528G>A p.L176= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as rs1305343222; called by muse, mutect2, varscan2
- C4orf54 | c.5292C>A p.I1764= | Silent (SNP) | VAF 39/181 reads (22%) | called by muse, mutect2, varscan2
- CLK1 | c.208C>A p.R70= | Silent (SNP) | VAF 65/326 reads (20%) | called by muse, mutect2, varscan2
- CTRB1 | c.654C>A p.V218= | Silent (SNP) | VAF 48/180 reads (27%) | called by muse, mutect2, varscan2
- CYP7A1 | c.1356C>T p.H452= | Silent (SNP) | VAF 28/239 reads (12%) | catalogued as rs964395133, COSV56962190, COSV56963046; called by muse, mutect2, varscan2
- DNAAF1 | c.840T>C p.D280= | Silent (SNP) | VAF 68/349 reads (19%) | called by muse, mutect2, varscan2
- EDNRB | c.1002G>A p.T334= (on ENST00000377211 / NM_001201397.1; = p.T244= on NM_000115.5) | Silent (SNP) | VAF 20/332 reads (6%) | catalogued as rs186620070; ClinVar: likely benign; called by muse, mutect2
- FBXO41 | c.2370C>T p.C790= | Silent (SNP) | VAF 22/464 reads (5%) | called by muse, mutect2
- GLI2 | c.180G>A p.A60= | Silent (SNP) | VAF 37/759 reads (5%) | catalogued as rs771240808; called by muse, mutect2
- GOLGA6L6 | c.1443G>A p.K481= | Silent (SNP) | VAF 109/1070 reads (10%) | called by muse, varscan2
- GPR61 | c.831C>T p.H277= | Silent (SNP) | VAF 60/203 reads (30%) | catalogued as rs541186557; called by muse, mutect2, varscan2
- GRAMD1A | c.933G>A p.V311= | Silent (SNP) | VAF 131/460 reads (28%) | called by muse, mutect2, varscan2
- HPS3 | c.822G>A p.L274= | Silent (SNP) | VAF 28/288 reads (10%) | called by muse, mutect2
- HUWE1 | c.3294G>T p.A1098= | Silent (SNP) | VAF 28/263 reads (11%) | catalogued as COSV53336969; called by muse, mutect2, varscan2
- ICAM5 | c.1488G>C p.V496= | Silent (SNP) | VAF 14/211 reads (7%) | called by muse, mutect2
- IRX4 | c.1377C>A p.T459= | Silent (SNP) | VAF 46/210 reads (22%) | called by muse, mutect2, varscan2
- ITIH2 | c.598C>T p.L200= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV64435301; called by muse, mutect2, varscan2
- JPH2 | c.1326C>A p.I442= | Silent (SNP) | VAF 108/439 reads (25%) | called by muse, mutect2, varscan2
- KALRN | c.7455G>A p.G2485= (on ENST00000360013 / NM_001024660.4; = p.G788= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 120/265 reads (45%) | catalogued as rs763122117, COSV52253591; called by muse, mutect2, varscan2
- MAGEB16 | c.855C>A p.T285= | Silent (SNP) | VAF 12/181 reads (7%) | called by muse, mutect2
- NBPF15 | c.462G>A p.L154= | Silent (SNP) | VAF 97/542 reads (18%) | called by muse, mutect2, varscan2
- NEDD4L | c.1900A>C p.R634= (on ENST00000400345 / NM_001144967.3; = p.R614= on NM_015277.6) | Silent (SNP) | VAF 18/115 reads (16%) | called by muse, mutect2, varscan2
- NTRK1 | c.891C>T p.H297= | Silent (SNP) | VAF 86/358 reads (24%) | catalogued as rs1553262169; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR13C5 | c.804T>C p.L268= | Silent (SNP) | VAF 44/135 reads (33%) | called by muse, mutect2, varscan2
- OR5F1 | c.919A>C p.R307= | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- OR8H1 | c.81C>G p.L27= | Silent (SNP) | VAF 36/154 reads (23%) | called by muse, mutect2, varscan2
- P2RY1 | c.381G>A p.Q127= | Silent (SNP) | VAF 118/605 reads (20%) | catalogued as rs766915687; called by muse, mutect2, varscan2
- PCDHB7 | c.2022G>A p.P674= | Silent (SNP) | VAF 22/785 reads (3%) | catalogued as rs782796386; called by muse, mutect2
- PKHD1 | c.5445C>A p.T1815= | Silent (SNP) | VAF 177/378 reads (47%) | called by muse, mutect2, varscan2
- PLCD1 | c.2046A>T p.P682= | Silent (SNP) | VAF 148/514 reads (29%) | called by muse, mutect2, varscan2
- POTEA | c.1395T>G p.V465= (on ENST00000519951 / NM_001005365.2; = p.V419= on NM_001002920.1) | Silent (SNP) | VAF 16/266 reads (6%) | called by muse, mutect2
- RAPGEF4 | c.2820G>A p.T940= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs373268327; called by muse, mutect2, varscan2
- ROCK2 | c.792A>C p.S264= | Silent (SNP) | VAF 129/291 reads (44%) | called by muse, mutect2, varscan2
- ROS1 | c.6708T>C p.S2236= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs746997621; called by mutect2, varscan2
- SERPINI2 | c.750C>A p.I250= | Silent (SNP) | VAF 47/308 reads (15%) | called by muse, mutect2, varscan2
- SLC35F1 | c.561C>A p.I187= | Silent (SNP) | VAF 89/238 reads (37%) | catalogued as COSV64504816; called by muse, mutect2, varscan2
- SLC52A1 | c.1257C>G p.S419= | Silent (SNP) | VAF 103/340 reads (30%) | called by muse, mutect2, varscan2
- SLC5A5 | c.1110C>T p.L370= | Silent (SNP) | VAF 115/526 reads (22%) | called by muse, mutect2, varscan2
- SLIT2 | c.3988T>C p.L1330= | Silent (SNP) | VAF 20/216 reads (9%) | catalogued as COSV56566010; called by muse, mutect2
- SOX7 | c.393G>A p.P131= | Silent (SNP) | VAF 31/284 reads (11%) | catalogued as rs139002697; called by muse, mutect2, varscan2
- SPAG4 | c.1269G>A p.V423= | Silent (SNP) | VAF 20/202 reads (10%) | called by muse, mutect2
- SYCE1L | c.189G>A p.K63= | Silent (SNP) | VAF 25/218 reads (11%) | called by muse, mutect2, varscan2
- TAZ | c.513T>C p.H171= | Silent (SNP) | VAF 54/564 reads (10%) | called by muse, mutect2
- TFDP1 | c.744C>T p.S248= | Silent (SNP) | VAF 78/403 reads (19%) | catalogued as rs758785229; called by muse, mutect2, varscan2
- UBR1 | c.2790A>G p.Q930= | Silent (SNP) | VAF 14/201 reads (7%) | called by muse, mutect2
- ZFHX4 | c.4872A>T p.A1624= | Silent (SNP) | VAF 32/148 reads (22%) | called by muse, mutect2, varscan2
- ZFR | c.639A>T p.I213= | Silent (SNP) | VAF 41/365 reads (11%) | called by muse, mutect2, varscan2
- ZNF99 | c.537C>T p.S179= | Silent (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- ABI3BP | c.1576+8088G>T | Intron (SNP) | VAF 14/342 reads (4%) | called by muse, mutect2
- AC010255.2 | c.-12A>G | 5'UTR (SNP) | VAF 67/347 reads (19%) | called by muse, mutect2, varscan2
- AKR1D1 | c.690-153G>A | Intron (SNP) | VAF 38/440 reads (9%) | catalogued as rs765166626; called by muse, mutect2
- AL021368.4 | n.38A>G | RNA (SNP) | VAF 126/301 reads (42%) | catalogued as rs775205129; called by muse, mutect2, varscan2
- CACNB2 | c.120+16C>T | Intron (SNP) | VAF 73/263 reads (28%) | called by muse, mutect2, varscan2
- CTNND2 | c.2638-1053G>A | Intron (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- DLL3 | c.*21G>T | 3'UTR (SNP) | VAF 19/275 reads (7%) | called by muse, mutect2
- DPY19L2P2 | n.335C>T | RNA (SNP) | VAF 32/129 reads (25%) | called by muse, mutect2, varscan2
- EIF4E | c.-59C>A | 5'UTR (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- FAM50A | c.781-12C>G | Intron (SNP) | VAF 41/351 reads (12%) | called by muse, mutect2, varscan2
- FHOD3 | c.1197-4674C>A | Intron (SNP) | VAF 18/330 reads (5%) | called by muse, mutect2
- FTL | c.-35C>A | 5'UTR (SNP) | VAF 34/298 reads (11%) | catalogued as rs763129553; called by muse, varscan2
- GNPTG | c.110+14C>T | Intron (SNP) | VAF 40/207 reads (19%) | called by muse, mutect2, varscan2
- LINC01193 | n.875G>C | RNA (SNP) | VAF 68/264 reads (26%) | catalogued as rs1488563382; called by muse, mutect2, varscan2
- LRATD1 | c.*124G>T | 3'UTR (SNP) | VAF 18/28 reads (64%) | catalogued as rs1242481964; called by muse, mutect2, varscan2
- MARCHF1 | c.242+763A>C | Intron (SNP) | VAF 15/204 reads (7%) | called by muse, mutect2
- MDM1 | c.-7G>T | 5'UTR (SNP) | VAF 32/135 reads (24%) | called by muse, mutect2, varscan2
- METTL2B | c.*721A>G | 3'UTR (SNP) | VAF 10/180 reads (6%) | catalogued as rs1386784188, COSV52310130; called by muse, mutect2
- MIR612 | chr11:65444403 C>T | 5'Flank (SNP) | VAF 14/174 reads (8%) | called by muse, mutect2
- NKD2 | c.*149del | 3'UTR (DEL) | VAF 44/227 reads (19%) | called by mutect2, pindel, varscan2
- POLR2G | c.123-310G>T | Intron (SNP) | VAF 14/75 reads (19%) | called by muse, mutect2, varscan2
- PTGER3 | c.*24-12887G>T | Intron (SNP) | VAF 36/268 reads (13%) | catalogued as COSV63392283; called by muse, mutect2, varscan2
- TNIP3 | c.946+714_946+721del | Intron (DEL) | VAF 18/97 reads (19%) | called by mutect2, pindel
- VCL | c.783+2822C>A | Intron (SNP) | VAF 29/153 reads (19%) | called by muse, mutect2, varscan2
- VGLL3 | c.937+5526G>C | Intron (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- VPS11 | c.-308C>T | 5'UTR (SNP) | VAF 31/387 reads (8%) | called by muse, mutect2
- ZBTB18 | c.-14-2384_-14-2383del | Intron (DEL) | VAF 42/200 reads (21%) | called by mutect2, pindel, varscan2
